Somatic mutation profile of tumor specimen TCGA-05-5715-01A (aliquot TCGA-05-5715-01A-01D-1625-08) from TCGA case TCGA-05-5715, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.5 years (25,383 days).
Specimen TCGA-05-5715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3a4473b-398f-410c-940e-66e6b43792ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-5715-10A (Blood Derived Normal), aliquot TCGA-05-5715-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a06d22e0-4cbb-4bd7-ad0f-e08c1f5ac64a

The open-access MAF lists 130 somatic variants for this specimen: 94 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 29, Nonsense Mutation 6, Frame Shift Del 4, 5'Flank 2, Frame Shift Ins 2, Splice Region 2, Intron 2, 3'UTR 1, In Frame Del 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 24/66 reads (36%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AKNAD1 | c.2493G>C p.R831S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs769163754, COSV64172340; called by muse, varscan2
- AMFR | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV51921616; called by muse, mutect2, varscan2
- ARHGEF12 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV63104896; called by muse, mutect2, varscan2
- ARID1A | c.2260C>T p.Q754* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | catalogued as rs1195496548, COSV61378336; called by muse, mutect2
- ASTN1 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs762828793, COSV56070182, COSV99923743; called by muse, mutect2, varscan2
- ATP6V1D | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53599600; called by muse, mutect2, varscan2
- ATP8B3 | c.3305G>A p.R1102H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs756195898, COSV59543118; called by muse, mutect2, varscan2
- C1R | c.1809G>C p.L603F (on ENST00000536053 / NM_001354346.2; = p.L589F on NM_001733.7) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.02); catalogued as COSV101605609, COSV73382991; called by muse, mutect2, varscan2
- C1orf127 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV100983518, COSV65436208; called by muse, mutect2, varscan2
- C3 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV55573653; called by muse, mutect2, varscan2
- CAND1 | c.1912T>C p.S638P | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73389627; called by muse, mutect2, varscan2
- CCDC83 | c.866C>T p.T289I (on ENST00000342404 / NM_001286159.2; = p.T320I on NM_173556.5) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1307399163, COSV54702055; called by muse, mutect2, varscan2
- CD99L2 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV60936452; called by muse, mutect2, varscan2
- CDC20 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs755545971, COSV60522193; called by muse, mutect2, varscan2
- CDT1 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56348527; called by muse, mutect2, varscan2
- CLHC1 | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1268903753, COSV100811500; called by muse, mutect2, varscan2
- COBL | c.2580G>C p.Q860H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as rs779535304, COSV54346703, COSV54347332; called by muse, mutect2, varscan2
- COBL | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV54346715; called by muse, mutect2, varscan2
- COBLL1 | c.694C>T p.Q232* (on ENST00000392717; = p.Q194* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV52068441, COSV52074317; called by muse, mutect2, varscan2
- COL25A1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs751717158, COSV67650641; called by muse, mutect2, varscan2
- CRB1 | c.4003G>A p.D1335N | Missense Mutation (SNP) | VAF 140/301 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV66330715; called by muse, mutect2, varscan2
- CTNNA2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777032066, COSV63569988, COSV63590877; called by muse, mutect2, varscan2
- DMD | c.9257C>A p.P3086H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58912712; called by muse, mutect2, varscan2
- DOCK11 | c.4916C>T p.A1639V | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs370101788, COSV52234125; called by muse, mutect2, varscan2
- DUSP6 | c.1110G>C p.Q370H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54378446; called by muse, mutect2, varscan2
- DYSF | c.5695G>A p.E1899K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV50368826; called by muse, mutect2, varscan2
- EFHB | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55548656; called by muse, mutect2, varscan2
- EIF3L | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as COSV101094579, COSV67740245; called by muse, mutect2, varscan2
- EWSR1 | c.48G>A p.Q16= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as rs763137483, COSV99328637; called by muse, mutect2, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs35774809; called by mutect2, pindel, varscan2
- FTL | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53170348, COSV99509248; called by muse, varscan2
- GPR179 | c.3080G>A p.R1027Q (on ENST00000621958; = p.R1026Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs751002235; called by muse, mutect2, varscan2
- GPR45 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs757651651, COSV51522993, COSV51525815; called by muse, mutect2, varscan2
- GRM1 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51154535; called by muse, mutect2, varscan2
- H2BC4 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as COSV58414957, COSV58416232; called by muse, mutect2, varscan2
- HAGHL | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as COSV52405908, COSV99284623; called by muse, mutect2
- HMCN1 | c.6812C>T p.A2271V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs747638841, COSV54890259; called by muse, mutect2, varscan2
- HOXA1 | c.652G>T p.G218W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56066376; called by muse, varscan2
- HSPG2 | c.9658G>A p.E3220K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.983); catalogued as COSV65933233; called by muse, mutect2, varscan2
- IFIH1 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55126961; called by muse, mutect2, varscan2
- IL10RB | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615636; called by muse, mutect2, varscan2
- KIFAP3 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV63034188; called by muse, mutect2, varscan2
- LMOD1 | c.1688G>C p.G563A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV66172779; called by muse, mutect2, varscan2
- MAGEA10 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867080597, COSV54884049; called by muse, mutect2
- MGA | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54953414, COSV54954701, COSV54961704; called by muse, mutect2, varscan2
- MPDZ | c.4514G>C p.G1505A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV59918411; called by muse, mutect2, varscan2
- NKX2-1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as rs1004953614, COSV100702052; called by muse, mutect2
- NPAP1 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.685); catalogued as COSV61507407; called by muse, mutect2, varscan2
- NPM2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs752056694, COSV57075732; called by muse, mutect2, varscan2
- OR4C3 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60586467, COSV60588117; called by muse, mutect2, varscan2
- OR4K13 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV59859738; called by muse, mutect2, varscan2
- OR4Q3 | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV59178742; called by muse, mutect2, varscan2
- PDZRN4 | c.2894G>A p.R965Q (on ENST00000402685 / NM_001164595.2; = p.R707Q on NM_013377.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.226); catalogued as rs1422938315, COSV54191692; called by muse, mutect2, varscan2
- PLEKHG1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV62047711; called by muse, mutect2
- PRORP | c.1451A>G p.Y484C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs890706900, COSV51618482; called by muse, mutect2, varscan2
- PSMC3IP | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53817181, COSV99519112; called by muse, mutect2, varscan2
- PSMD11 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV55578926; called by muse, mutect2, varscan2
- PTK6 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV53917002; called by muse, mutect2, varscan2
- PYGB | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.31); catalogued as rs758229367, COSV53818840; called by muse, mutect2, varscan2
- RAD54B | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60250299, COSV60251837; called by muse, mutect2, varscan2
- RGS16 | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 31/114 reads (27%) | catalogued as rs771954411, COSV62375731; called by muse, mutect2, varscan2
- RNASEL | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1273818084, COSV62376903; called by muse, mutect2, varscan2
- RNF111 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV62085328; called by muse, mutect2, varscan2
- RNF168 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.745); catalogued as COSV58837942; called by muse, mutect2, varscan2
- SCN11A | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56570987, COSV56572449; called by muse, mutect2, varscan2
- SESTD1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100091005, COSV58931401; called by muse, mutect2, varscan2
- SETD3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); catalogued as COSV59284574; called by muse, mutect2, varscan2
- SLC12A9 | c.1041G>C p.L347F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV51933805; called by muse, mutect2, varscan2
- SLC17A9 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV100947819, COSV64847325; called by muse, mutect2, varscan2
- SLC7A14 | c.543G>T p.G181= | Splice Region (SNP) | VAF 14/26 reads (54%) | catalogued as COSV51582545; called by muse, mutect2
- SLC9A6 | c.1573A>G p.R525G | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65788044; called by muse, mutect2, varscan2
- SMAD4 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as COSV61688361; called by muse, mutect2, varscan2
- SUOX | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs905674841, COSV56268556; called by muse, mutect2, varscan2
- TAF3 | c.68G>T p.W23L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV60206929; called by muse, mutect2, varscan2
- TBC1D19 | c.795G>C p.L265F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53516394; called by muse, mutect2
- TLK2 | c.1258G>A p.E420K (on ENST00000326270 / NM_001284333.2; = p.E398K on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV58300475; called by muse, mutect2, varscan2
- TMEM132D | c.2856C>G p.F952L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV67160529; called by muse, mutect2, varscan2
- TREML1 | c.608G>C p.R203T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.272); catalogued as COSV100914275, COSV64191252; called by muse, mutect2, varscan2
- TRO | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV51502103; called by muse, mutect2, varscan2
- TTC21A | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1220723292, COSV57185497; called by muse, mutect2, varscan2
- UBQLNL | c.994A>C p.I332L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as COSV100975654; called by muse, mutect2, varscan2
- WAPL | c.2779G>C p.E927Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1564565056, COSV53935442; called by muse, mutect2, varscan2
- XRCC5 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 49/136 reads (36%) | catalogued as COSV67536322; called by muse, mutect2, varscan2
- ZBTB45 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99564648; called by muse, mutect2
- ZNF180 | c.2047C>G p.H683D | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55421516; called by muse, mutect2, varscan2
- ZNF836 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100441338; called by muse, mutect2, varscan2
- ZXDA | c.1552T>A p.C518S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV62388052; called by muse, mutect2, varscan2
- ARNT | c.1733del p.P578Lfs*28 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- IRX1 | c.866del p.P289Qfs*9 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- KMT2A | c.5118del p.D1707Ifs*2 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- NFKBIZ | c.581dup p.T195Nfs*13 | Frame Shift Ins (INS) | VAF 20/38 reads (53%) | called by mutect2, pindel, varscan2
- RANGRF | c.252_281del p.V85_A94del | In Frame Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel
- UBQLN1 | c.1423dup p.T475Nfs*27 | Frame Shift Ins (INS) | VAF 12/25 reads (48%) | called by mutect2, pindel, varscan2
- ARMH4 | c.1539G>T p.L513= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV50764920; called by muse, mutect2, varscan2
- ATE1 | c.345C>T p.P115= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV56436812; called by muse, mutect2, varscan2
- ATP10A | c.2259C>T p.I753= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1412115068, COSV63515562, COSV63517782; called by muse, mutect2, varscan2
- BMPR1A | c.810C>T p.S270= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100923717; called by muse, mutect2, varscan2
- CENPF | c.276C>G p.V92= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV65275253; called by muse, mutect2, varscan2
- CHRNB2 | c.429C>T p.I143= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as rs369264665; called by muse, mutect2, varscan2
- CX3CR1 | c.273G>A p.L91= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV64194001; called by muse, mutect2, varscan2
- CYP11B1 | c.633G>C p.L211= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV52827546, COSV52830486; called by muse, mutect2, varscan2
- DSC3 | c.834G>A p.T278= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs926254758, COSV64573128; called by muse, mutect2
- DSP | c.4932G>A p.L1644= | Silent (SNP) | VAF 42/62 reads (68%) | catalogued as COSV65793039; called by muse, mutect2, varscan2
- F13B | c.9G>A p.L3= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV66374015; called by muse, mutect2, varscan2
- FTL | c.321G>T p.L107= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs11553263, COSV53170352; called by muse, varscan2
- HTT | c.3561G>A p.E1187= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV61862678; called by muse, mutect2, varscan2
- MAN2B2 | c.357G>C p.V119= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV53453253; called by muse, mutect2
- MINDY2 | c.795C>T p.P265= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57506865; called by muse, mutect2, varscan2
- NF1 | c.6519T>G p.A2173= (on ENST00000358273 / NM_001042492.3; = p.A2152= on NM_000267.3) | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV62204968; called by muse, mutect2, varscan2
- NFIC | c.318C>G p.L106= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV100545043, COSV59412869; called by muse, mutect2, varscan2
- NRK | c.2616A>T p.P872= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV54597390; called by muse, mutect2, varscan2
- OPN3 | c.399C>T p.T133= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs766992784, COSV59364472; called by muse, mutect2, varscan2
- OR2F2 | c.756C>T p.Y252= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs757273782, COSV101283861; called by muse, mutect2, varscan2
- OR4D6 | c.213C>T p.I71= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV55659002, COSV55659579; called by muse, mutect2, varscan2
- OTX1 | c.15C>T p.L5= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV56994820, COSV56996173; called by muse, mutect2, varscan2
- PRAMEF15 | c.1332G>A p.V444= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- PUS7L | c.2079G>A p.L693= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV61261965; called by muse, mutect2, varscan2
- SAMD9L | c.1518C>T p.S506= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs560813720, COSV59081443; called by muse, mutect2, varscan2
- SLC39A13 | c.51C>G p.L17= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV100712708; called by muse, mutect2, varscan2
- SP140 | c.1491G>A p.R497= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV59450227; called by muse, mutect2
- ZEB2 | c.735C>G p.L245= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs1431555828, COSV57950475, COSV57957259; called by muse, mutect2, varscan2
- ZNF648 | c.225C>A p.G75= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs911721500, COSV60570527, COSV60571182; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849292 G>C | 5'Flank (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918810 C>G | 5'Flank (SNP) | VAF 9/14 reads (64%) | catalogued as rs570433496, COSV100711419, COSV62704012; called by muse, mutect2, varscan2
- BAX | c.474+42C>G | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99509283; called by muse, mutect2, varscan2
- MIR520G | n.87G>T | RNA (SNP) | VAF 14/42 reads (33%) | catalogued as rs774325298; called by muse, mutect2, varscan2
- NT5C2 | c.688-685C>G | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- R3HDML | chr20:44355828 C>T | 3'Flank (SNP) | VAF 20/29 reads (69%) | catalogued as rs761046168, COSV53836118; called by muse, varscan2
- UVSSA | c.*9838C>T | 3'UTR (SNP) | VAF 11/65 reads (17%) | catalogued as rs1340857950, COSV61349057; called by muse, mutect2, varscan2
